CPTAC case C3N-02783 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/58024352-41ea-400e-82d6-592f1d7677a6

Demographics
Sex at birth: female; Race: asian; Year of birth: 1993; Vital status: Alive; Country of birth: China.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Age at diagnosis: 24.3 years (8,889 days); Year of diagnosis: 2017; Last known disease status: Tumor free; Days to last known disease status: 1,416 days (3.9 years); Progression or recurrence: no; Days to last follow up: 1,416 days (3.9 years).
   Pathology details: Greatest tumor dimension: 8 cm.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (5 entries)
- Days to follow up: 433 days (1.2 years); Disease response: Tumor Free; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 772 days (2.1 years); Disease response: Tumor Free; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 977 days (2.7 years); Disease response: Tumor Free; Karnofsky performance status: 60; ECOG performance status: 3.
- Days to follow up: 977 days (2.7 years); Disease response: Complete Response; Karnofsky performance status: 60; ECOG performance status: 3.
- Days to follow up: 1,416 days (3.9 years); Disease response: Tumor Free; Karnofsky performance status: 60; ECOG performance status: 3.

Other clinical attributes
- Weight: 43 kg; Height: 153 cm; BMI: 18.37.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02783-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -9 days; Initial weight: 600 mg; Time between excision and freezing: 9 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02783-25: Section location: Parietal Lobe and Occipital Lobe and Temporal Lobe; Percent tumor nuclei: 80; Percent necrosis: 7.
- Sample C3N-02783-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -9 days; Method of sample procurement: Blood Draw.
